MMRF case MMRF_1393 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7dc31268-639a-487c-a031-76c2335c77c5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,357 days); ISS stage: II; Days to last known disease status: 1,476 days (4.0 years); Days to last follow up: 1,476 days (4.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 323 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 490 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,209 days (3.3 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 132 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 134 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 323 days; Days to treatment end: 590 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 490 days (1.3 years); Days to treatment end: 590 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,210 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.721 mg/dL; Immunoglobulin G 20.2 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.92 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.32 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 7.6 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.4 mg/dL.
- Day 85 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.989 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.25 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 204 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.923 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.31 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 4.18 mmol/L.
- Day 267 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 7.74 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 365 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6.27 mmol/L.
- Day 463 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.655 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.748 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 4.07 mmol/L.
- Day 547 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.798 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.869 mg/dL; Immunoglobulin G 5.31 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.35 mmol/L.
- Day 621 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.585 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.817 mg/dL; Immunoglobulin G 5.16 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 715 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 8.18 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 827 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.39 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.31 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.62 mmol/L.
- Day 883 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 6.38 mmol/L.
- Day 1,023 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.85 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.62 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.46 mmol/L.
- Day 1,086 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.53 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.68 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 6 mmol/L.
- Day 1,210 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.12 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.13 mmol/L.
- Day 1,268 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.32 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.62 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.13 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.24 mmol/L.
- Day 1,345 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.77 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 5.17 mmol/L.
- Day 1,476 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.61 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.61 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day 1: Weight: 82 kg; Height: 166 cm.

Biospecimens (2 samples)
- Sample MMRF_1393_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1393_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
